Somatic mutation profile of tumor specimen 0DJVPS from CCDI case PBBXME, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 19.9 years (7,258 days).
Specimen 0DJVPS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c12ccc36-f4e8-4ba3-97ad-4bc50555fe4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVPF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a214d46-d31e-4026-ac8a-3cc599df72d3

The open-access MAF lists 26 somatic variants for this specimen: 12 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 9, Missense Mutation 8, Intron 3, Splice Site 2, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.1622G>A p.R541Q (on ENST00000404938 / NM_001163941.2; = p.R96Q on NM_178559.6) | Missense Mutation (SNP) | VAF 391/869 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776819013, COSV51718331; called by muse, mutect2
- DNAI1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 353/784 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs754452989; called by muse, mutect2, varscan2
- GGT7 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 342/763 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs866226326, COSV100322124; called by muse, mutect2, varscan2
- KLHL26 | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 185/378 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs1568465728, COSV99963149; called by muse, mutect2, varscan2
- ZNF285 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 306/680 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs765848183, COSV58410103; called by muse, mutect2, varscan2
- GGA2 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 334/729 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GSE1 | c.959_960dup p.E321Rfs*18 | Frame Shift Ins (INS) | VAF 392/1014 reads (39%) | called by mutect2, pindel, varscan2
- GTF2I | c.2641+2dup p.X881_splice (on ENST00000573035 / NM_032999.4; = p.X840_splice on NM_001518.5) | Splice Site (INS) | VAF 229/894 reads (26%) | called by mutect2, pindel, varscan2
- HERC5 | c.1567T>C p.S523P | Missense Mutation (SNP) | VAF 214/430 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGAV | c.2592+1G>A p.X864_splice | Splice Site (SNP) | VAF 152/370 reads (41%) | called by muse, mutect2, varscan2
- OR2A42 | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 133/441 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, varscan2
- ZIC1 | c.1201dup p.Y401Lfs*43 | Frame Shift Ins (INS) | VAF 384/953 reads (40%) | called by mutect2, pindel, varscan2
- CAPN15 | c.1296C>T p.C432= | Silent (SNP) | VAF 303/618 reads (49%) | catalogued as rs753468615; called by muse, mutect2, varscan2
- CCDC168 | c.4629C>T p.N1543= | Silent (SNP) | VAF 300/704 reads (43%) | catalogued as rs151111334, COSV70556452; called by muse, mutect2, varscan2
- FAM166C | c.9C>T p.S3= | Silent (SNP) | VAF 166/393 reads (42%) | called by muse, mutect2, varscan2
- GABRA6 | c.48T>C p.N16= | Silent (SNP) | VAF 358/818 reads (44%) | called by muse, mutect2, varscan2
- GRHL2 | c.1827C>T p.L609= | Silent (SNP) | VAF 260/548 reads (47%) | called by muse, mutect2, varscan2
- GYG1 | c.219C>A p.T73= | Silent (SNP) | VAF 277/632 reads (44%) | called by muse, mutect2, varscan2
- LMTK3 | c.462C>T p.S154= | Silent (SNP) | VAF 186/476 reads (39%) | catalogued as rs372816721; called by muse, mutect2, varscan2
- OPRD1 | c.810C>T p.F270= | Silent (SNP) | VAF 281/617 reads (46%) | catalogued as rs749081223, COSV52384050; called by muse, mutect2, varscan2
- TBC1D10C | c.960C>T p.P320= | Silent (SNP) | VAF 216/436 reads (50%) | catalogued as rs140449515, COSV56701995, COSV56704397; called by muse, mutect2, varscan2
- B4GALT7 | c.-61C>G | 5'UTR (SNP) | VAF 92/173 reads (53%) | called by muse, mutect2, varscan2
- CCNDBP1 | c.*83G>A | 3'UTR (SNP) | VAF 195/382 reads (51%) | catalogued as rs1567266662; called by muse, mutect2, varscan2
- L3MBTL1 | c.2123+27G>A | Intron (SNP) | VAF 360/749 reads (48%) | catalogued as rs545234707; called by muse, mutect2, varscan2
- PIK3R4 | c.3906+36A>T | Intron (SNP) | VAF 191/366 reads (52%) | called by muse, mutect2, varscan2
- UFM1 | c.59+173G>A | Intron (SNP) | VAF 346/750 reads (46%) | called by muse, mutect2, varscan2
